Gene-level copy-number profile of specimen HCM-BROD-0208-C16-85B from HCMI case HCM-BROD-0208-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G3; Age at diagnosis: 71.2 years (26,023 days).
Specimen HCM-BROD-0208-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f6900b48-b544-4898-be8b-a329c1e06f52.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0208-C16-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/61f4a00d-6b2f-4352-850e-e6fa14a618be

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 510; copy number 1: 423; copy number 2: 40,947; copy number 3: 14,963; copy number 4: 1,734; copy number 5: 209; copy number 6: 27; copy number 7: 21; copy number 8: 2; copy number 9: 6; copy number 10: 7; copy number 11: 19; copy number 12: 22; copy number 17: 9; copy number 19: 1; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 324 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,573,801–248,645,278, 6 genes, copy number 5: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr2:38,814–46,870, 1 gene, copy number 5: FAM110C.
- chr2:5,313,740–5,314,134, 1 gene, copy number 5: AC073143.1.
- chr2:6,258,348–6,341,788, 1 gene, copy number 5: AC017053.1.
- chr2:6,917,412–7,077,916, 2 genes, copy number 5 (within-gene range 4–5): RNF144A, AC068481.1.
- chr2:15,903,669–20,246,387, 59 genes, copy number 10–20: AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1, KCNS3, AC079802.1, AC079148.1, RDH14, NT5C1B-RDH14, NT5C1B, RNU6-1215P, AC106053.1, LINC01376, MIR4757, OSR1, AC010096.1, LINC01808, AC019055.1, CISD1P1, LINC00954, TTC32, AC013400.1, WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P.
- chr2:87,700,984–87,825,952, 4 genes, copy number 5: ANAPC1P4, PLGLB2, RGPD2, MTATP8P2.
- chr2:88,414,898–88,575,610, 5 genes, copy number 5 (within-gene range 4–5): RNU6-1007P, RPL38P6, FOXI3, TEX37, AC104134.1.
- chr2:89,009,982–89,020,686, 2 genes, copy number 5 (within-gene range 4–5): IGKV1-9, IGKV2-10.
- chr2:89,040,224–95,149,434, 120 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:95,789,654–97,100,874, 48 genes, copy number 6–7: GPAT2P1, LINC00342, ANKRD36C, RN7SL210P, FAHD2CP, GPAT2, ADRA2B, ASTL, DUSP2, AC012307.1, STARD7, STARD7-AS1, TMEM127, CIAO1, SNRNP200, AC021188.1, ITPRIPL1, NCAPH, NEURL3, AC013270.1, ARID5A, KANSL3, FER1L5, LMAN2L, CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P.
- chr9:61,581,813–61,627,683, 2 genes, copy number 8: AL935212.3, FAM242D.
- chr10:27,331,357–27,414,368, 6 genes, copy number 5: AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3.
- chr11:89,869,282–89,921,767, 6 genes, copy number 9: TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1.
- chr16:33,094,204–33,570,935, 13 genes, copy number 5 (within-gene range 4–5): HERC2P8, AC145350.4, AC145350.1, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr16:33,687,025–33,810,767, 5 genes, copy number 5: BMS1P8, ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3.
- chr19:39,196,964–39,709,444, 43 genes, copy number 5: NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14.

Autosomal genes at a single copy (total copy number 1): 243. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
